Gene-level copy-number profile of tumor specimen BLGSP-71-27-00411-01A from CGCI case BLGSP-71-27-00411, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 40.2 years (14,685 days).
Specimen BLGSP-71-27-00411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 158b558b-a4f3-474a-8c74-fb40fae21610.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-27-00411-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,755 have no estimate.
https://portal.gdc.cancer.gov/files/48842bbf-0c33-4543-b663-20ad7c3fd995

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 4,100; copy number 2: 53,828; copy number 3: 882; copy number 4: 25; copy number 5: 4; copy number 6: 14.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr8:12,064,389–12,177,550, 10 genes (within-gene range 0–1): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,446–522,928, 14 genes, copy number 6: AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 1,257. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
